Somatic mutation profile of tumor specimen 0DU9N3 from CCDI case PBCKUC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,321 days).
Specimen 0DU9N3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c2cd09b-0b2f-4ef3-92ef-88b9d3a50018.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9NF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c63c74d-2e13-4b6c-bf3b-921f8b8db412

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 3, Intron 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.974G>A p.R325H (on ENST00000399959; = p.R326H on NM_001356.5) | Missense Mutation (SNP) | VAF 301/313 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs797045025, CM158024, COSV101302329; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CUX1 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 296/653 reads (45%) | catalogued as COSV99471484; called by muse, mutect2, varscan2
- GSE1 | c.981delinsGG p.S327Rfs*24 | Frame Shift Ins (INS) | VAF 232/1017 reads (23%) | catalogued as COSV53671646; called by mutect2*, pindel, varscan2*
- TAS1R2 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 258/580 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.04); catalogued as rs754453014, COSV64746691; called by muse, mutect2, varscan2
- EIF2AK4 | c.1945G>T p.V649L | Missense Mutation (SNP) | VAF 140/269 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GSE1 | c.980dup p.S327Rfs*24 | Frame Shift Ins (INS) | VAF 196/652 reads (30%) | called by mutect2, varscan2
- PCDHB9 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 220/556 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); called by muse, mutect2
- PCDHGA6 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 185/395 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TRAPPC6A | c.21_22insTG p.E8Wfs*26 (on ENST00000585934 / NM_001270891.2; = p.E8Wfs*23 on NM_024108.3) | Frame Shift Ins (INS) | VAF 47/257 reads (18%) | called by mutect2, pindel, varscan2
- HTRA1 | c.1425C>T p.P475= | Silent (SNP) | VAF 222/579 reads (38%) | catalogued as rs779158785, COSV64565063; called by muse, mutect2, varscan2
- PGBD2 | c.1641C>T p.F547= | Silent (SNP) | VAF 116/270 reads (43%) | catalogued as rs368036878; called by muse, mutect2, varscan2
- PRAMEF11 | c.747C>T p.Y249= | Silent (SNP) | VAF 48/272 reads (18%) | catalogued as rs752921773; called by muse, varscan2
- NIP7 | c.*24C>T | 3'UTR (SNP) | VAF 176/413 reads (43%) | catalogued as rs145746516; called by muse, mutect2, varscan2
- OBSCN | c.22664-47C>T | Intron (SNP) | VAF 62/323 reads (19%) | catalogued as rs758286985; called by muse, mutect2, varscan2
